TCGA case TCGA-D7-6524 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Greater Poland Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7ef3f065-1928-4a58-b5a6-76dddb8488cf

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Poland; Age at index: 53 years; Vital status: Alive.

Diagnoses (2)
1. Carcinoma, diffuse type (the primary disease): ICD-O-3 morphology code: 8145/3; ICD-10 code: C16.3; Tissue or organ of origin: Gastric antrum; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 53.5 years (19,532 days); Year of diagnosis: 2010; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 6; Lymph nodes tested: 16.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Carcinoma, diffuse type), site: Lymph node, NOS. Age at diagnosis: 55.0 years (20,075 days); Days to diagnosis: 543 days (1.5 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS to Locoregional Site.

Follow-up (2 entries)
- Days to follow up: 21 days; Disease response: Tumor Free.
- Day 543 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 543 days (1.5 years).

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-D7-6524-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.8; Shortest dimension: 0.6.
  Slide TCGA-D7-6524-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25.
  Slide TCGA-D7-6524-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-D7-6524-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-D7-6524-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Diffuse Type; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Antrum/Distal; Lymph nodes examined: Yes; Cancer procurement city: Poznan; Antireflux treatment: No; History barretts esophageal indicator: No.
- Follow-up form: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event site: Non-regional / Distant Lymph Nodes; Treatment outcome first course: Progressive Disease; Treatment outcome at TCGA followup: Progressive Disease.
- Follow-up form, New neoplasm event types: New tumor event type: Locoregional Recurrence.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 543 days; disease-specific survival: no event (censored), 543 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 543 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-D7-6524-01A-11D-1799-01): tumor purity 0.18, ploidy 2.13, whole-genome doublings 0.
